Somatic mutation profile of tumor specimen TCGA-DD-A11D-01A (aliquot TCGA-DD-A11D-01A-11D-A12Z-10) from TCGA case TCGA-DD-A11D, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.5 years (21,003 days).
Specimen TCGA-DD-A11D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c1b88e8-8679-43c7-a578-1b92f9cc1cd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A11D-11A (Solid Tissue Normal), aliquot TCGA-DD-A11D-11A-12D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8e5a6c0-6aae-46f5-9830-dfb5572f524a

The open-access MAF lists 143 somatic variants for this specimen: 104 protein-altering or splice-affecting, 38 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 38, Frame Shift Del 7, Splice Site 4, In Frame Del 2, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 14/195 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2
- A1BG | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54050685; called by muse, mutect2, varscan2
- ABCA12 | c.6806A>G p.K2269R (on ENST00000272895 / NM_173076.3; = p.K1951R on NM_015657.3) | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV55957584; called by muse, mutect2, varscan2
- ACAT2 | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58458669; called by muse, mutect2, varscan2
- ACSF2 | c.1553A>G p.E518G | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51972254; called by muse, mutect2, varscan2
- ADAM2 | c.847C>A p.Q283K | Missense Mutation (SNP) | VAF 94/266 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.105); catalogued as COSV55861596; called by muse, varscan2
- ADAMTS10 | c.2624G>A p.R875K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV54354425; called by muse, mutect2, varscan2
- ANK1 | c.2391A>G p.L797= | Splice Region (SNP) | VAF 31/83 reads (37%) | catalogued as COSV55880308; called by muse, mutect2, varscan2
- ATP7A | c.154T>A p.Y52N | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58445718; called by muse, mutect2, varscan2
- BMPER | c.952A>T p.N318Y | Missense Mutation (SNP) | VAF 113/388 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV51814389, COSV51817398; called by muse, mutect2, varscan2
- BRD1 | c.2950G>C p.E984Q (on ENST00000216267 / NM_001349940.1; = p.E1115Q on NM_001304808.3) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV53457094; called by muse, mutect2, varscan2
- C11orf16 | c.788T>C p.F263S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV58167126; called by muse, mutect2, varscan2
- C16orf82 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1178198947; called by muse, mutect2, varscan2
- CD248 | c.1540C>G p.P514A | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV60936369; called by muse, mutect2, varscan2
- CELF1 | c.643G>T p.G215* | Nonsense Mutation (SNP) | VAF 81/189 reads (43%) | catalogued as COSV100136754, COSV60111645; called by muse, mutect2, varscan2
- CKMT2 | c.153C>A p.S51R | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0.374); catalogued as COSV54173048, COSV54174630; called by muse, mutect2, varscan2
- CLSTN2 | c.1142T>C p.I381T | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs778316944, COSV71720600; called by muse, mutect2, varscan2
- CMTM2 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV51748592; called by muse, mutect2, varscan2
- CYP2W1 | c.871C>A p.L291M | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); catalogued as rs753062234, COSV58269970; called by muse, mutect2, varscan2
- DACT1 | c.1089C>G p.N363K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs776288208, COSV60020579; called by muse, mutect2, varscan2
- DHTKD1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs971222205, COSV53803282; called by muse, mutect2, varscan2
- DNAH8 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV59442532, COSV59449141; called by muse, mutect2, varscan2
- DOCK10 | c.1719C>G p.D573E | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778060237, COSV51386989; called by muse, mutect2, varscan2
- DSCAM | c.767A>G p.Y256C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV68025915; called by muse, mutect2, varscan2
- DUSP22 | c.483T>A p.D161E | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753022752, COSV60526529; called by muse, mutect2, varscan2
- ECPAS | c.127A>G p.S43G | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52196341; called by muse, mutect2, varscan2
- EDA | c.719A>T p.K240I | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV65781133; called by muse, mutect2, varscan2
- EEF1AKMT4 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV56181829; called by muse, mutect2, varscan2
- EFCAB13 | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.83); catalogued as rs758376019, COSV58948032; called by muse, varscan2
- EFCAB13 | c.2012del p.L671* | Frame Shift Del (DEL) | VAF 33/99 reads (33%) | catalogued as COSV58953483; called by pindel, varscan2
- FANCM | c.5429G>T p.R1810I | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as COSV57500510; called by muse, mutect2, varscan2
- FER | c.641T>C p.M214T | Missense Mutation (SNP) | VAF 118/220 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs770017609, COSV55290036; called by muse, mutect2, varscan2
- GLI2 | c.1469T>C p.F490S (on ENST00000361492 / NM_001374353.1; = p.F507S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58040859; called by muse, mutect2, varscan2
- GLO1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64905148; called by muse, varscan2
- GRIA3 | c.2476G>A p.G826S | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52057913; called by muse, mutect2, varscan2
- GRIK2 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.028); catalogued as COSV59732686; called by muse, mutect2
- HIF3A | c.1652G>T p.C551F (on ENST00000377670 / NM_152795.4; = p.C482F on NM_022462.4) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV52198013, COSV52201989; called by muse, mutect2, varscan2
- HK3 | c.2548A>G p.K850E | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99458366; called by muse, mutect2, varscan2
- HTRA2 | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV51207267; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1485A>T p.R495S | Missense Mutation (SNP) | VAF 87/227 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.906); catalogued as COSV56258083; called by muse, mutect2, varscan2
- IL20RA | c.865-1G>C p.X289_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV57358019; called by muse, mutect2, varscan2
- IRS4 | c.2544C>A p.N848K | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV64533598; called by muse, mutect2, varscan2
- ISX | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV58086449; called by muse, mutect2, varscan2
- KIF13A | c.1468C>G p.Q490E | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52449556; called by muse, mutect2, varscan2
- KIT | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.112); catalogued as rs1553892672, COSV55398698, COSV99855727; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCN8 | c.94-1G>T p.X32_splice (on ENST00000612714 / NM_001345934.1; = p.X9_splice on NM_178469.3) | Splice Site (SNP) | VAF 17/45 reads (38%) | catalogued as COSV60209953; called by muse, mutect2, varscan2
- LRRC8D | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV61578932; called by muse, mutect2, varscan2
- LZTS3 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.445); catalogued as COSV61277646; called by muse, mutect2, varscan2
- LZTS3 | c.459+2T>C p.X153_splice | Splice Site (SNP) | VAF 23/68 reads (34%) | catalogued as rs1363430722, COSV61277660; called by muse, mutect2, varscan2
- MACC1 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60542373; called by muse, mutect2, varscan2
- MAP1B | c.4951C>A p.Q1651K | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV57098252; called by muse, mutect2, varscan2
- MBTPS1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs778500373, COSV58570495; called by muse, mutect2, varscan2
- MISP | c.1752G>T p.Q584H | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99296761; called by muse, mutect2, varscan2
- MISP | c.1753A>G p.N585D | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99296763; called by muse, mutect2, varscan2
- MON1B | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780179568, COSV50245753; called by muse, mutect2, varscan2
- NFYA | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV58198509; called by muse, mutect2, varscan2
- NLRC4 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs200929188, COSV61592076; called by muse, mutect2, varscan2
- NLRP3 | c.1946C>A p.P649H | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.131); catalogued as COSV60223635; called by muse, mutect2, varscan2
- NPAP1 | c.391C>A p.R131S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100275235, COSV61504673; called by muse, mutect2
- OGFRL1 | c.336C>G p.I112M | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.64); catalogued as COSV64971880; called by muse, mutect2
- OR51T1 | c.816G>T p.R272S | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs772529902, COSV59025161, COSV59027687; called by muse, mutect2, varscan2
- OR8J1 | c.74T>C p.I25T | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as COSV57318020; called by muse, mutect2, varscan2
- PAK6 | c.1667C>A p.P556H | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53045431; called by muse, mutect2, varscan2
- PASD1 | c.1543A>T p.M515L | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.003); catalogued as COSV64855094; called by muse, mutect2, varscan2
- PHKA1 | c.1607A>G p.N536S | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as COSV59805423; called by muse, mutect2, varscan2
- PIWIL1 | c.1642A>G p.K548E | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55346336; called by muse, mutect2, varscan2
- PKHD1L1 | c.4261A>G p.T1421A | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV65742162; called by muse, mutect2, varscan2
- POLR2G | c.283-1G>T p.X95_splice | Splice Site (SNP) | VAF 13/190 reads (7%) | catalogued as COSV57135121; called by muse, mutect2
- POU3F2 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV60408811; called by muse, mutect2, varscan2
- PPFIA3 | c.302A>G p.E101G | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100494858; called by muse, mutect2, varscan2
- PYGM | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.263); catalogued as COSV51216403; called by muse, mutect2, varscan2
- RCSD1 | c.394T>A p.S132T | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as COSV63258767; called by muse, mutect2, varscan2
- RFX5 | c.1697G>T p.S566I | Missense Mutation (SNP) | VAF 32/489 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51838913, COSV51840208; called by muse, mutect2
- RGMB | c.316C>G p.H106D (on ENST00000513185 / NM_001366508.1; = p.H147D on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57565420; called by muse, mutect2, varscan2
- RGMB | c.1310T>A p.L437* (on ENST00000513185 / NM_001366508.1; = p.L478* on NM_001012761.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 129/232 reads (56%) | catalogued as COSV57565427; called by muse, mutect2, varscan2
- RGS9 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV52225071; called by muse, mutect2, varscan2
- RIPOR1 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1413114941, COSV50223108; called by muse, mutect2, varscan2
- RNASET2 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.074); catalogued as COSV50351483, COSV99218486; called by muse, mutect2, varscan2
- RNF123 | c.1300G>T p.V434F | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.68); PolyPhen benign (0.364); catalogued as COSV100570982, COSV59686785; called by muse, mutect2, varscan2
- SAV1 | c.891T>A p.N297K | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61204797; called by muse, mutect2, varscan2
- SCN3B | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV54798748; called by muse, mutect2, varscan2
- SCYL2 | c.1846A>G p.M616V | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as rs1469022906, COSV62568596; called by muse, mutect2, varscan2
- SEPTIN2 | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as COSV63632312; called by muse, mutect2, varscan2
- SLC9A6 | c.493T>A p.Y165N | Missense Mutation (SNP) | VAF 151/401 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV65787895; called by muse, mutect2, varscan2
- TBX4 | c.1498G>A p.G500R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV53606774; called by muse, mutect2, varscan2
- TGFB3 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); catalogued as COSV53169514; called by muse, mutect2, varscan2
- TSPAN18 | c.95T>C p.I32T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs985569616, COSV60883555; called by muse, mutect2, varscan2
- TST | c.342G>T p.W114C | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50765021; called by muse, mutect2, varscan2
- TTN | c.71674C>A p.P23892T (on ENST00000591111; = p.P16468T on NM_003319.4) | Missense Mutation (SNP) | VAF 86/234 reads (37%) | PolyPhen probably damaging (0.999); catalogued as COSV60023635; called by muse, mutect2, varscan2
- USP6NL | c.513T>A p.H171Q | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV53210999; called by muse, mutect2, varscan2
- UTP15 | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV57140816; called by muse, mutect2, varscan2
- ZNF239 | c.1182_1183del p.R395Sfs*18 | Frame Shift Del (DEL) | VAF 66/214 reads (31%) | catalogued as rs770789292; called by mutect2, pindel, varscan2
- ZNF559-ZNF177 | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58673358; called by muse, mutect2, varscan2
- ZNF831 | c.4691A>C p.K1564T | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as COSV64039683; called by muse, mutect2, varscan2
- ATP2B4 | c.369_391+1del | In Frame Del (DEL) | VAF 56/262 reads (21%) | called by mutect2, pindel, varscan2
- CSMD1 | c.978del p.S327Afs*11 | Frame Shift Del (DEL) | VAF 45/136 reads (33%) | called by mutect2, pindel, varscan2
- DNAH1 | c.4534del p.V1512Sfs*3 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- ERRFI1 | c.477_483del p.E160Sfs*13 | Frame Shift Del (DEL) | VAF 23/44 reads (52%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.152T>A p.L51Q | Missense Mutation (SNP) | VAF 108/925 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.795); called by muse, varscan2
- HTT | c.6086_6087insA p.Q2030Pfs*43 | Frame Shift Ins (INS) | VAF 18/58 reads (31%) | called by mutect2, pindel*, varscan2
- LRRC8D | c.1339A>G p.R447G | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2
- OVCH1 | c.253_260del p.A85Lfs*7 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- PLXNB1 | c.896_898delinsTT p.S299Ffs*107 | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | called by pindel, varscan2*
- ZNF772 | c.152_157del p.L51_Y52del | In Frame Del (DEL) | VAF 69/198 reads (35%) | called by mutect2, pindel, varscan2
- ABCG8 | c.204G>T p.L68= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV55392892; called by muse, mutect2, varscan2
- ACTL8 | c.387G>C p.L129= | Silent (SNP) | VAF 47/107 reads (44%) | catalogued as COSV64861279; called by muse, mutect2, varscan2
- CHIA | c.928C>T p.L310= (on ENST00000343320; = p.L202= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 65/194 reads (34%) | catalogued as rs779690824, COSV58475073; called by muse, mutect2, varscan2
- CLPS | c.285C>T p.S95= | Silent (SNP) | VAF 40/168 reads (24%) | catalogued as COSV52566278; called by muse, mutect2, varscan2
- COL4A4 | c.4026T>A p.P1342= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as COSV61631743; called by muse, mutect2
- FRRS1L | c.864A>G p.L288= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs930729318, COSV73746541; called by muse, mutect2, varscan2
- GABRA3 | c.363A>T p.T121= | Silent (SNP) | VAF 13/132 reads (10%) | catalogued as COSV64798211; called by muse, mutect2, varscan2
- GAD1 | c.1587T>A p.P529= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as COSV64025753; called by muse, mutect2, varscan2
- GPATCH2L | c.1227A>G p.S409= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV55048216; called by muse, mutect2, varscan2
- GTDC1 | c.201G>T p.V67= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV53993796; called by muse, mutect2, varscan2
- HEBP2 | c.534C>T p.G178= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as COSV62928250; called by muse, mutect2, varscan2
- HPR | c.693C>T p.N231= | Silent (SNP) | VAF 63/138 reads (46%) | catalogued as COSV57182382; called by muse, mutect2, varscan2
- HTR2A | c.1056C>T p.S352= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as COSV66327172; called by muse, mutect2, varscan2
- INTS1 | c.801G>T p.L267= | Silent (SNP) | VAF 38/54 reads (70%) | catalogued as COSV67177295; called by muse, mutect2, varscan2
- MAGOHB | c.45C>T p.H15= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV57898383; called by muse, mutect2, varscan2
- MAP1B | c.2382T>A p.A794= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as COSV57098241; called by muse, mutect2, varscan2
- MAP3K10 | c.816G>A p.P272= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs750198182, COSV53422030; called by muse, mutect2, varscan2
- NTRK2 | c.1938G>T p.T646= (on ENST00000323115 / NM_001369534.1; = p.T662= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV52862772, COSV52884670; called by muse, mutect2, varscan2
- OR2L8 | c.591A>T p.T197= | Silent (SNP) | VAF 80/335 reads (24%) | catalogued as COSV61726637; called by muse, mutect2
- OR5P3 | c.702C>A p.R234= | Silent (SNP) | VAF 63/134 reads (47%) | catalogued as COSV60429237; called by muse, mutect2, varscan2
- PCDH7 | c.780G>T p.L260= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV62338498; called by mutect2, varscan2
- PCDHA1 | c.1971G>A p.P657= | Silent (SNP) | VAF 96/158 reads (61%) | catalogued as rs376407441; called by muse, mutect2, varscan2
- PCDHA6 | c.1752A>T p.S584= | Silent (SNP) | VAF 20/366 reads (5%) | catalogued as COSV65343765; called by muse, mutect2
- PDXDC1 | c.666G>A p.E222= | Silent (SNP) | VAF 70/345 reads (20%) | catalogued as COSV57906388; called by muse, mutect2, varscan2
- PGR | c.1119G>A p.A373= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs984715438, COSV54800668; called by muse, mutect2, varscan2
- PLXNA1 | c.984G>A p.L328= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV52525605; called by muse, mutect2, varscan2
- PRDX1 | c.564C>T p.V188= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as rs1302821236, COSV53113627, COSV53115142; called by muse, mutect2, varscan2
- SLC6A20 | c.1296C>T p.A432= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV62071195; called by muse, mutect2
- TFPI2 | c.483A>G p.P161= | Silent (SNP) | VAF 66/111 reads (59%) | catalogued as COSV55990517; called by muse, mutect2, varscan2
- TMEM108 | c.450C>T p.T150= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs368132206; called by muse, mutect2, varscan2
- TRIML2 | c.193T>C p.L65= | Silent (SNP) | VAF 40/148 reads (27%) | catalogued as COSV58715901, COSV58718684; called by muse, mutect2, varscan2
- XRRA1 | c.804C>A p.I268= | Silent (SNP) | VAF 105/230 reads (46%) | catalogued as COSV58497591; called by muse, mutect2, varscan2
- ZDHHC4 | c.615T>G p.A205= | Silent (SNP) | VAF 164/317 reads (52%) | catalogued as COSV60106458; called by muse, mutect2, varscan2
- ZNF267 | c.465T>G p.S155= | Silent (SNP) | VAF 72/197 reads (37%) | catalogued as COSV56252509; called by muse, mutect2, varscan2
- ZNF280B | c.858T>C p.S286= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as rs1365026790, COSV64528824; called by muse, mutect2, varscan2
- ZNF33A | c.267C>T p.H89= (on ENST00000458705 / NM_006974.3; = p.H90= on NM_006954.2) | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as rs1365158913, COSV56724640; called by muse, mutect2, varscan2
- ZNF408 | c.1215G>T p.G405= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV61238038; called by muse, mutect2, varscan2
- ZNF536 | c.441G>C p.L147= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV62823375; called by muse, mutect2, varscan2
- DCHS2 | n.7638T>G | RNA (SNP) | VAF 55/145 reads (38%) | catalogued as COSV61771241, COSV61780797; called by muse, mutect2, varscan2
